Gene-level copy-number profile of tumor specimen TCGA-XF-AAML-01A from TCGA case TCGA-XF-AAML, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.1 years (27,422 days).
Specimen TCGA-XF-AAML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.12cc440c-3723-4c92-b989-7c35cd03cbe4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAML-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3036a602-4b1c-4a00-8f7e-60d38f469739

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 868; copy number 2: 8,016; copy number 3: 19,688; copy number 4: 21,922; copy number 5: 4,938; copy number 6: 3,354; copy number 7: 283; copy number 8: 500; copy number 9: 22; copy number 10: 39; copy number 12: 61; copy number 19: 99; copy number 20: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAML-01A-11D-A42D-01): tumor purity 0.74, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 242 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–152,047,907, 99 genes, copy number 19 (within-gene range 8–19) (broad region; genes not listed).
- chr6:15,934,782–22,654,455, 85 genes, copy number 10–20 (within-gene range 5–20) (broad region; genes not listed).
- chr11:57,338,352–57,819,546, 29 genes, copy number 10 (within-gene range 2–10): P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1, RN7SL605P, TIMM10, SMTNL1, UBE2L6, RPS4XP13, SERPING1, AP000662.1, MIR130A, YPEL4, CLP1, ZDHHC5, MED19, AP001931.2, TMX2, PPIAP42, SELENOH, AP001931.1, BTBD18, CTNND1.
- chr11:70,187,788–71,252,577, 22 genes, copy number 9: ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr16:5,260,686–5,838,661, 7 genes, copy number 10: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3, LINC01570, MIR8065, AC012175.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
